Surgical pathology report (de-identified scan), TCGA case TCGA-FK-A3SH, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-FK-A3SH-01A (Primary Tumor).

- LAB RESULTS

	3/30/12	

SURG PATH REPORT
COLLECTION DATE/TIME:

PATH#:

1st Specimen collected on
Accessioned on

FINAL DIAGNOSIS ----- Pathologist:

1. PRETRACHEAL LYMPH NODE (BIOPSY): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.

2. RULE IN PARATHYROID (BIOPSY): PARATHYROID TISSUE (30.0 MG).

3. THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy.

TUMOR SITE:

Right and left lobes.

HISTOLOGIC TYPE:

Papillary carcinoma.

TUMOR SIZE (LARGEST NODULE):

Greatest dimension: 3.0 cm (left), 0.4 cm (right).

FOCALITY:

Multifocal.

LYMPH NODES (ALL PARTS):

Metastatic carcinoma in two (2) of eight (8) lymph nodes.

EXTENT OF INVASION (STAGING):

PRIMARY TUMOR:

pT2: Tumor >2.0 cm but <4.0 cm, limited to thyroid.

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to Level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes.

DISTANT METASTASIS:

PMx: Cannot be assessed.

MARGINS (ALL THAT APPLY):

Margins are uninvolved.

VENOUS/LYMPHATIC INVASION:

Present.

ADDITIONAL PATHOLOGIC FINDINGS (ALL THAT APPLY):

Nodular hyperplasia, benign thymic tissue.

4. LEFT CENTRAL NECK (DISSECTION): METASTATIC PAPILLARY THYROID

CARCINOMA (LARGEST FOCUS, 0.4 CM) IN TWO (2) OF FOUR (4) LYMPH NODES.

Final Report Signed on

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

5-12
AD

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file f86d745e-0c00-449a-a318-448fdd66a081 (TCGA-FK-A3SH.0BFE6CA6-DA46-4162-A403-3F51F9F9EABA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).